Gene-level copy-number profile of tumor specimen TCGA-LN-A49W-01A from TCGA case TCGA-LN-A49W, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 73.7 years (26,910 days).
Specimen TCGA-LN-A49W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.a54c9f39-f46c-49ab-b642-8decbbc971fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS.
https://portal.gdc.cancer.gov/files/ba221f4a-6244-4dfe-9bee-f972d1b9b06a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 412; copy number 2: 27,613; copy number 3: 19,568; copy number 4: 8,420; copy number 5: 2,506; copy number 6: 474; copy number 7: 38; copy number 8: 238; copy number 9: 68; copy number 11: 61; copy number 13: 78; copy number 17: 122; copy number 20: 85; copy number 21: 3; copy number 28: 6; copy number 54: 6; copy number 63: 8; copy number 81: 13; copy number 101: 2.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,690,225–60,732,636, 3 genes: PPIAP70, AC104164.1, PPIAP71.
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr9:20,331,446–25,678,440, 87 genes (broad region; genes not listed).
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,708 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–9,198,906, 313 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:39,081,316–42,051,784, 92 genes, copy number 17–63 (within-gene range 3–63) (broad region; genes not listed).
- chr1:48,172,972–48,248,644, 3 genes, copy number 7: AL109659.1, SLC5A9, AL109659.2.
- chr1:60,515,716–62,178,675, 13 genes, copy number 5–101 (within-gene range 2–101): LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P.
- chr1:100,896,076–101,996,926, 19 genes, copy number 6 (within-gene range 3–6): SLC30A7, HNRNPA1P68, DPH5, AC093157.2, AC093157.1, AC093157.3, AC119501.1, AL109741.1, S1PR1, AL109741.2, PPIAP7, LINC01307, LINC01709, RNU6-965P, RPSAP19, OLFM3, RNU6-352P, AL356280.1, DNAJA1P5.
- chr1:102,876,467–103,555,239, 6 genes, copy number 6 (within-gene range 4–6): COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3.
- chr1:115,471,941–116,297,621, 19 genes, copy number 28–81: AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, AL355538.1.
- chr1:116,909,149–120,914,238, 84 genes, copy number 20 (broad region; genes not listed).
- chr1:120,942,600–120,942,763, 1 gene, copy number 20: RNVU1-4.
- chr1:143,343,180–153,428,401, 425 genes, copy number 5 (broad region; genes not listed).
- chr2:205,253,304–206,000,858, 6 genes, copy number 8 (within-gene range 2–8): AC008171.1, NRP2, AC007362.1, RN7SKP178, PPIAP68, AC007679.1.
- chr3:70,605,420–74,521,140, 60 genes, copy number 5–8: AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3.
- chr3:77,567,508–78,525,485, 8 genes, copy number 6: AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3.
- chr3:151,637,174–161,821,908, 168 genes, copy number 5 (broad region; genes not listed).
- chr3:164,670,878–198,222,513, 636 genes, copy number 5–8 (broad region; genes not listed).
- chr6:49,115,537–50,773,033, 27 genes, copy number 6: AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D.
- chr6:55,753,653–65,707,226, 73 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr6:71,028,582–71,058,476, 1 gene, copy number 9 (within-gene range 3–9): AL096709.1.
- chr7:70,972–9,985,895, 214 genes, copy number 6–9 (broad region; genes not listed).
- chr7:26,152,198–27,492,765, 68 genes, copy number 6 (broad region; genes not listed).
- chr7:39,888,375–40,134,622, 7 genes, copy number 7: RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA.
- chr7:40,151,613–40,154,151, 1 gene, copy number 7: THUMPD3P1.
- chr7:53,655,508–57,837,046, 163 genes, copy number 5–6 (broad region; genes not listed).
- chr8:63,136,223–69,178,189, 91 genes, copy number 6–17 (broad region; genes not listed).
- chr8:101,287,445–108,489,196, 113 genes, copy number 5 (broad region; genes not listed).
- chr8:123,851,987–124,120,061, 1 gene, copy number 5 (within-gene range 4–5): FER1L6.
- chr8:123,984,138–141,662,209, 225 genes, copy number 5 (broad region; genes not listed).
- chr10:60,684,505–65,880,289, 52 genes, copy number 5–6 (within-gene range 4–6): ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2, MYL6P3, AL513321.1, AL592466.1, LINC01515.
- chr11:68,870,664–71,252,577, 61 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr11:72,285,495–72,434,680, 1 gene, copy number 5 (within-gene range 2–5): CLPB.
- chr11:72,354,516–74,254,703, 63 genes, copy number 5 (broad region; genes not listed).
- chr11:74,252,414–74,252,552, 1 gene, copy number 5: AP000577.1.
- chr12:18,080,869–19,376,400, 15 genes, copy number 5: RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr12:19,413,153–19,446,055, 3 genes, copy number 5: PDCD5P1, AC091805.2, RNU6-254P.
- chr15:26,261,669–34,437,466, 212 genes, copy number 5–6 (broad region; genes not listed).
- chr18:47,390–1,310,018, 38 genes, copy number 5 (within-gene range 4–5): TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3.
- chr18:41,341,319–41,632,185, 2 genes, copy number 6 (within-gene range 4–6): AC079052.1, KC6.
- chr19:21,221,645–28,727,680, 160 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:30,028,741–37,304,395, 263 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 404. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
